Somatic mutation profile of tumor specimen C3N-02930-01 (aliquot CPT0184810038) from CPTAC case C3N-02930, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.9 years (22,240 days).
Specimen C3N-02930-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce92571e-cf4f-43f5-8d1d-2550c784f4fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02930-31 (Blood Derived Normal), aliquot CPT0184870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1b1866a-97cb-4626-a933-441a878d2e80

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, RNA 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCYAP1R1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); catalogued as rs1307857192, COSV100416360, COSV58441241; called by muse, mutect2
- ATP6V1G2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV58215138; called by muse, mutect2
- CFTR | c.2301G>C p.Q767H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386366130; called by muse, mutect2
- GRM8 | c.2288G>A p.C763Y | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237114599; called by muse, mutect2
- KRT1 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1375564720, COSV52865403; called by muse, mutect2
- NUP205 | c.3739G>T p.A1247S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.9); catalogued as COSV53658653; called by muse, mutect2, varscan2
- PCDHB15 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 46/755 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV50859859; called by muse, mutect2
- XDH | c.3107G>A p.G1036E | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65151270; called by muse, mutect2
- DNAH17 | c.9731G>A p.W3244* | Nonsense Mutation (SNP) | VAF 52/437 reads (12%) | called by muse, mutect2, varscan2
- FBN1 | c.4534G>A p.D1512N | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.167); called by muse, mutect2
- H3C2 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 21/423 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- MSL1 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDUFV1 | c.914-8G>A | Splice Region (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- PIP5K1C | c.1772A>G p.K591R | Missense Mutation (SNP) | VAF 19/383 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2
- RYR2 | c.5788G>T p.D1930Y | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2
- TBC1D10C | c.426A>C p.Q142H | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TCF25 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- ZNF679 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); called by muse, mutect2
- ADA2 | c.1287G>A p.L429= (on ENST00000262607; = p.L188= on NM_177405.3) | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- CDH4 | c.480C>T p.N160= | Silent (SNP) | VAF 28/234 reads (12%) | catalogued as rs149210026; called by muse, mutect2, varscan2
- CRYBB1 | c.531C>T p.Y177= | Silent (SNP) | VAF 26/560 reads (5%) | catalogued as rs141329615; called by muse, mutect2
- NEFL | c.528G>A p.A176= | Silent (SNP) | VAF 13/226 reads (6%) | catalogued as rs760320750; called by muse, mutect2
- PKD1 | c.843C>T p.H281= | Silent (SNP) | VAF 26/498 reads (5%) | catalogued as rs760237424, COSV99238465; called by muse, mutect2
- PXDNL | c.3264G>A p.P1088= | Silent (SNP) | VAF 14/247 reads (6%) | catalogued as COSV62486212; called by muse, mutect2
- SLC26A9 | c.1998C>T p.I666= | Silent (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- TLDC2 | c.625C>T p.L209= | Silent (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- WIZ | c.1863G>A p.E621= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1364766940, COSV99653292; called by muse, varscan2
- MORF4 | n.448T>C | RNA (SNP) | VAF 18/299 reads (6%) | called by muse, mutect2
- TMEM183B | n.844G>A | RNA (SNP) | VAF 19/340 reads (6%) | catalogued as rs776679628; called by muse, mutect2
